Somatic mutation profile of tumor specimen C3L-07987-04 (aliquot CPT0453040006) from CPTAC case C3L-07987, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 70.5 years (25,751 days).
Specimen C3L-07987-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3347103-785f-4628-8cf0-1ae0fa70d93d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07987-31 (Blood Derived Normal), aliquot CPT0453160003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c324b904-1789-4a8d-9ef6-7311421bb18a

The open-access MAF lists 168 somatic variants for this specimen: 110 protein-altering or splice-affecting, 55 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 55, Nonsense Mutation 6, Frame Shift Del 3, Splice Region 1, 5'UTR 1, Translation Start Site 1, In Frame Del 1, RNA 1, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 46/404 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs139552940, CM099129; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 57/364 reads (16%) | catalogued as rs1064796453; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs797045041, COSV58292419; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.12592C>T p.R4198* | Nonsense Mutation (SNP) | VAF 89/570 reads (16%) | catalogued as rs587783685, CM122102, COSV56409006, COSV56429446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPAST | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060502227, CD052507, CM000436, CM101456, COSV59514516; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGO2 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 135/453 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55048523; called by muse, mutect2, varscan2
- AR | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 72/531 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV65955458; called by muse, mutect2, varscan2
- AUTS2 | c.2767G>A p.G923S | Missense Mutation (SNP) | VAF 99/628 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1449975429; called by muse, mutect2, varscan2
- CACNA1I | c.4288G>A p.V1430M | Missense Mutation (SNP) | VAF 71/552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60809804; called by muse, mutect2, varscan2
- CCDC120 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 117/807 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199599217; called by muse, mutect2, varscan2
- CDH9 | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50253829, COSV99145286, COSV99163241; called by muse, mutect2, varscan2
- CHRM2 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 61/419 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV57768532; called by muse, mutect2, varscan2
- CYLC1 | c.454A>C p.T152P | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100255731, COSV61412924; called by muse, mutect2, varscan2
- CYP11B1 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 75/741 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1515479; called by muse, mutect2, varscan2
- ESRP1 | c.641C>G p.T214S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as rs753536820; called by muse, mutect2, varscan2
- FAM83H | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 138/968 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs782125363, COSV101186987; called by muse, mutect2, varscan2
- FBN1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as rs749467972; called by muse, mutect2, varscan2
- FLNA | c.5342A>G p.N1781S (on ENST00000369850 / NM_001110556.2; = p.N1773S on NM_001456.3) | Missense Mutation (SNP) | VAF 94/708 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs373089783; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FNDC1 | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 118/603 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV51945437; called by muse, mutect2, varscan2
- GLIPR1L2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV57555488; called by muse, mutect2, varscan2
- GNAS | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 123/677 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as rs1270188558, COSV58336274; called by muse, mutect2, varscan2
- GREB1L | c.2563G>A p.V855M | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs767849450; called by muse, mutect2, varscan2
- H2AC12 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 75/496 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100804780; called by muse, mutect2
- HUWE1 | c.9520C>T p.R3174C | Missense Mutation (SNP) | VAF 73/526 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782714866; called by muse, mutect2, varscan2
- HUWE1 | c.9292C>T p.R3098* | Nonsense Mutation (SNP) | VAF 98/745 reads (13%) | catalogued as COSV53344338; called by muse, mutect2, varscan2
- IGF2BP1 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 52/323 reads (16%) | catalogued as COSV51730140; called by muse, mutect2, varscan2
- JAG2 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1455218970; called by muse, mutect2
- KLHL36 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 89/417 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377188394, COSV50718043; called by muse, mutect2, varscan2
- LCTL | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 63/449 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1392515852, COSV58422018; called by muse, mutect2, varscan2
- LOXL3 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs575389607, COSV51207323; called by muse, mutect2, varscan2
- LRAT | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 80/500 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1223595259, COSV60477826, COSV60477929; called by muse, mutect2, varscan2
- LSP1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 71/441 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs772024277; called by muse, mutect2, varscan2
- LTBP2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 115/746 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1313818466, COSV100001374, COSV56212326; called by muse, mutect2, varscan2
- MAP2K7 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 36/696 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607626; called by muse, mutect2
- MTSS2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 108/688 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs747980657, COSV58698595; called by muse, mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 76/551 reads (14%) | catalogued as rs765184193; called by pindel, varscan2
- MYH7 | c.3802C>T p.R1268C | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100806113, COSV62519590; called by muse, mutect2, varscan2
- MYH7B | c.3191G>A p.R1064H | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs556514656; called by muse, mutect2
- NCEH1 | c.317C>T p.A106V (on ENST00000538775; = p.A74V on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/513 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as rs370462746; called by mutect2, varscan2
- NOVA1 | c.1296A>C p.L432F | Missense Mutation (SNP) | VAF 72/418 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV57484042; called by muse, mutect2, varscan2
- OR8G5 | c.886del p.D296Mfs*6 | Frame Shift Del (DEL) | VAF 38/286 reads (13%) | catalogued as COSV58381498; called by pindel, varscan2
- PCDH10 | c.2318G>T p.R773L | Missense Mutation (SNP) | VAF 95/567 reads (17%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.987); catalogued as COSV52100330; called by muse, varscan2
- PCDH12 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 73/589 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.594); catalogued as rs370147049; called by muse, mutect2, varscan2
- PCDHGB7 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 67/476 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs369649545; called by muse, mutect2, varscan2
- PDZD7 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 88/598 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as rs1280166252, COSV64647452; called by muse, mutect2, varscan2
- POU3F1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 94/646 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs754899429; called by muse, mutect2, varscan2
- PPP2R3B | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 145/948 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs767595543; called by muse, mutect2, varscan2
- PPP4R3C | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297303; called by muse, mutect2, varscan2
- RASGRF2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 34/249 reads (14%) | catalogued as rs376557330; called by muse, mutect2, varscan2
- RNF43 | c.471del p.T158Pfs*6 | Frame Shift Del (DEL) | VAF 103/382 reads (27%) | catalogued as rs1164873326, COSV101348565; called by mutect2, pindel, varscan2
- RP1 | c.5998T>G p.L2000V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV55121310; called by muse, mutect2, varscan2
- RRAGB | c.900G>T p.K300N (on ENST00000262850 / NM_016656.4; = p.K272N on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV53331977; called by mutect2, varscan2
- SALL3 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 107/731 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475797062, COSV101609958, COSV73305909; called by muse, mutect2, varscan2
- SELENBP1 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 60/403 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs955467467, COSV64372967; called by muse, mutect2, varscan2
- SETBP1 | c.2080G>T p.A694S | Missense Mutation (SNP) | VAF 66/398 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV56327546; called by muse, mutect2, varscan2
- SLC22A11 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 97/568 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs868032143, COSV57251559, COSV57253535; called by muse, mutect2, varscan2
- SLC8A1 | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV60500210; called by muse, mutect2, varscan2
- SLC8A1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60479849; called by muse, mutect2, varscan2
- SLITRK4 | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 85/734 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100567273; called by muse, mutect2, varscan2
- SYNE1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 57/405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575386895, COSV55044224, COSV99556733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX13C | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 130/490 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs913207753, COSV51707260; called by muse, mutect2, varscan2
- TLR4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 36/286 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV62922416; called by muse, varscan2
- TUBE1 | c.810G>A p.T270= | Splice Region (SNP) | VAF 12/149 reads (8%) | catalogued as rs781948733; called by muse, mutect2
- VRTN | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 75/658 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs888061162, COSV56442147, COSV99832405; called by muse, mutect2, varscan2
- WFIKKN1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 101/656 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as rs746301177; called by muse, mutect2, varscan2
- ZMYM3 | c.3280+1G>A p.X1094_splice | Splice Site (SNP) | VAF 36/337 reads (11%) | catalogued as COSV58740456; called by muse, mutect2, varscan2
- ZNF257 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV71309813, COSV71313366; called by muse, mutect2, varscan2
- ZNF579 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 82/584 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs1332010733, COSV57637565; called by muse, mutect2, varscan2
- ZNF716 | c.577T>A p.S193T | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV70779726; called by muse, mutect2
- AC013489.1 | c.821A>C p.E274A | Missense Mutation (SNP) | VAF 72/503 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARHGAP27 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 105/513 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1437A>T p.R479S | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ATR | c.7546A>G p.T2516A | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C5 | c.4299T>A p.S1433R | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.035); called by mutect2, varscan2
- CCDC141 | c.3478C>A p.Q1160K | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CFAP44 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHSY1 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.163T>A p.S55T | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNHD1 | c.13468C>A p.L4490I | Missense Mutation (SNP) | VAF 103/630 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- FAM186A | c.2542A>T p.N848Y | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- GPRASP1 | c.1264A>G p.S422G | Missense Mutation (SNP) | VAF 91/739 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HAS3 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 95/576 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- KDM5C | c.1249C>G p.P417A | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLF7 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 93/564 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- LAMP2 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LGR6 | c.728A>G p.Y243C (on ENST00000367278 / NM_001017403.1; = p.Y191C on NM_021636.3) | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- MAP3K15 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- MECOM | c.599T>C p.F200S (on ENST00000468789 / NM_001105078.4; = p.F388S on NM_004991.4) | Missense Mutation (SNP) | VAF 41/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC6 | c.3955T>A p.S1319T | Missense Mutation (SNP) | VAF 125/807 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEB | c.6505A>T p.K2169* | Nonsense Mutation (SNP) | VAF 48/309 reads (16%) | called by muse, mutect2, varscan2
- NRXN1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 102/656 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OGFRL1 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 15/429 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2
- OR10AC1 | c.128del p.N43Tfs*43 | Frame Shift Del (DEL) | VAF 74/558 reads (13%) | called by mutect2, pindel, varscan2
- PALM3 | c.502C>T p.P168S (on ENST00000340790; = p.P183S on NM_001145028.2) | Missense Mutation (SNP) | VAF 19/706 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2
- PGAM4 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 66/683 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- PKHD1L1 | c.7223C>A p.A2408E | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2
- PLEKHB2 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 70/553 reads (13%) | PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- PRKCQ | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTHLH | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SLC12A3 | c.2576G>A p.C859Y (on ENST00000563236 / NM_001126108.2; = p.C868Y on NM_000339.3) | Missense Mutation (SNP) | VAF 88/522 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SLC25A21 | c.467A>G p.Q156R | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by mutect2, varscan2
- SLITRK2 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 77/646 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SVIL | c.492T>A p.S164R | Missense Mutation (SNP) | VAF 82/500 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SYT3 | c.210_211insCC p.S71Pfs*31 | Frame Shift Ins (INS) | VAF 92/594 reads (15%) | called by mutect2, pindel, varscan2
- TCF7L1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 34/680 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2
- UBAP1L | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 87/693 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- UNC79 | c.385G>C p.G129R | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP5 | c.1175C>G p.P392R | Missense Mutation (SNP) | VAF 86/515 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13D | c.391T>G p.S131A | Missense Mutation (SNP) | VAF 56/373 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ZNF25 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACSM3 | c.609G>A p.E203= | Silent (SNP) | VAF 29/258 reads (11%) | called by muse, mutect2, varscan2
- ADAM32 | c.2208C>T p.S736= | Silent (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- ADGRL4 | c.15G>A p.P5= | Silent (SNP) | VAF 93/602 reads (15%) | catalogued as COSV66064525; called by muse, mutect2, varscan2
- ALOX5 | c.1422C>T p.D474= | Silent (SNP) | VAF 55/620 reads (9%) | catalogued as rs543892108, COSV65551206; called by muse, mutect2
- APC2 | c.5592G>A p.P1864= | Silent (SNP) | VAF 111/684 reads (16%) | catalogued as rs781702680; called by muse, mutect2, varscan2
- ASIP | c.330G>A p.P110= | Silent (SNP) | VAF 106/690 reads (15%) | catalogued as rs762757094; called by muse, mutect2, varscan2
- BNC2 | c.834A>T p.T278= | Silent (SNP) | VAF 51/437 reads (12%) | called by muse, mutect2, varscan2
- BX276092.9 | c.546G>A p.S182= | Silent (SNP) | VAF 62/489 reads (13%) | catalogued as rs1185978722; called by muse, mutect2, varscan2
- C2orf16 | c.4881G>T p.P1627= | Silent (SNP) | VAF 76/428 reads (18%) | called by muse, mutect2, varscan2
- CD1A | c.256T>C p.L86= | Silent (SNP) | VAF 95/537 reads (18%) | called by muse, mutect2, varscan2
- CLASP1 | c.321G>A p.V107= | Silent (SNP) | VAF 46/354 reads (13%) | catalogued as COSV55336493; called by muse, varscan2
- CRLS1 | c.126G>A p.L42= | Silent (SNP) | VAF 77/574 reads (13%) | called by muse, mutect2, varscan2
- CSMD1 | c.3693T>C p.R1231= (on ENST00000520002; = p.R1230= on NM_033225.6) | Silent (SNP) | VAF 68/536 reads (13%) | catalogued as rs767063687; called by muse, mutect2, varscan2
- CSPG4 | c.4626G>C p.G1542= | Silent (SNP) | VAF 90/541 reads (17%) | called by muse, mutect2, varscan2
- CTNND2 | c.633C>A p.G211= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- CYFIP1 | c.192C>T p.T64= | Silent (SNP) | VAF 49/397 reads (12%) | catalogued as rs150062205; called by muse, mutect2, varscan2
- DMRTA1 | c.948G>A p.K316= | Silent (SNP) | VAF 51/350 reads (15%) | called by muse, mutect2, varscan2
- DOCK9 | c.5871G>A p.K1957= (on ENST00000376460 / NM_001366676.2; = p.K1958= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/475 reads (16%) | catalogued as COSV59621520, COSV59637712; called by muse, mutect2, varscan2
- DOK6 | c.384C>T p.A128= | Silent (SNP) | VAF 34/358 reads (9%) | catalogued as rs773183518, COSV66935398; called by muse, mutect2
- EYA1 | c.1032C>T p.Y344= | Silent (SNP) | VAF 38/276 reads (14%) | catalogued as rs778091745, COSV58161038, COSV58163484; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLNC | c.7038C>T p.G2346= | Silent (SNP) | VAF 74/463 reads (16%) | called by muse, mutect2, varscan2
- FOXC2 | c.1431C>T p.C477= | Silent (SNP) | VAF 92/595 reads (15%) | catalogued as rs576674766; called by muse, mutect2, varscan2
- HMCN1 | c.14322C>T p.N4774= | Silent (SNP) | VAF 67/517 reads (13%) | catalogued as rs139398979; ClinVar: likely benign; called by muse, mutect2, varscan2
- HPN | c.1233C>T p.S411= | Silent (SNP) | VAF 85/557 reads (15%) | catalogued as rs778519202, COSV52883686; called by muse, mutect2, varscan2
- HPR | c.348C>T p.P116= | Silent (SNP) | VAF 88/600 reads (15%) | called by muse, mutect2, varscan2
- HRG | c.882A>G p.E294= | Silent (SNP) | VAF 82/682 reads (12%) | called by muse, mutect2, varscan2
- IGDCC4 | c.1062C>T p.F354= | Silent (SNP) | VAF 100/563 reads (18%) | catalogued as rs1033134454; called by muse, mutect2, varscan2
- IRX1 | c.1353G>A p.Q451= | Silent (SNP) | VAF 79/480 reads (16%) | called by muse, mutect2, varscan2
- KCNA1 | c.1137C>T p.Y379= | Silent (SNP) | VAF 85/537 reads (16%) | catalogued as rs759584837; called by muse, mutect2, varscan2
- LAMA2 | c.8628C>T p.A2876= | Silent (SNP) | VAF 84/461 reads (18%) | catalogued as rs376119947; called by muse, mutect2, varscan2
- MAGEB5 | c.309T>G p.T103= | Silent (SNP) | VAF 60/562 reads (11%) | catalogued as COSV104430992; called by muse, mutect2, varscan2
- MAP3K21 | c.939C>T p.P313= | Silent (SNP) | VAF 75/496 reads (15%) | catalogued as rs1294798585, COSV100786205, COSV100786301; called by muse, mutect2, varscan2
- MAP3K21 | c.1353G>T p.L451= | Silent (SNP) | VAF 61/482 reads (13%) | called by muse, mutect2, varscan2
- MEGF8 | c.4074G>A p.S1358= (on ENST00000251268 / NM_001271938.2; = p.S1291= on NM_001410.3) | Silent (SNP) | VAF 84/479 reads (18%) | catalogued as rs372557198; called by muse, mutect2, varscan2
- MPL | c.1071A>T p.R357= | Silent (SNP) | VAF 83/562 reads (15%) | called by muse, mutect2, varscan2
- NKX1-1 | c.576C>T p.D192= | Silent (SNP) | VAF 111/703 reads (16%) | catalogued as COSV101438004; called by muse, mutect2, varscan2
- NLRP5 | c.1455C>T p.D485= | Silent (SNP) | VAF 87/603 reads (14%) | catalogued as rs779934994; called by muse, mutect2, varscan2
- OR10K1 | c.324C>A p.G108= | Silent (SNP) | VAF 68/512 reads (13%) | called by muse, mutect2, varscan2
- P2RY4 | c.1047G>A p.A349= | Silent (SNP) | VAF 82/882 reads (9%) | catalogued as rs368227542, COSV65736440; called by muse, mutect2
- PCDHA2 | c.1287C>T p.D429= | Silent (SNP) | VAF 105/634 reads (17%) | called by muse, mutect2, varscan2
- PHEX | c.558C>T p.S186= | Silent (SNP) | VAF 93/647 reads (14%) | called by muse, mutect2, varscan2
- PHF8 | c.1509C>T p.P503= (on ENST00000357988 / NM_001184896.1; = p.P467= on NM_015107.3) | Silent (SNP) | VAF 86/852 reads (10%) | catalogued as COSV100154452; called by muse, mutect2
- RBP3 | c.1026G>A p.T342= | Silent (SNP) | VAF 117/589 reads (20%) | catalogued as rs781847771; called by muse, mutect2, varscan2
- RGS3 | c.2898C>T p.D966= (on ENST00000350696 / NM_001282923.2; = p.D685= on NM_130795.4) | Silent (SNP) | VAF 85/571 reads (15%) | catalogued as rs778110506, COSV100636939; called by muse, mutect2, varscan2
- RIBC1 | c.126C>T p.V42= | Silent (SNP) | VAF 73/599 reads (12%) | catalogued as COSV51448510; called by muse, mutect2, varscan2
- RTL5 | c.27C>T p.N9= | Silent (SNP) | VAF 37/602 reads (6%) | called by muse, mutect2
- SEL1L2 | c.1614G>A p.A538= | Silent (SNP) | VAF 30/295 reads (10%) | catalogued as rs368728589; called by muse, mutect2, varscan2
- SLC19A2 | c.495T>G p.T165= | Silent (SNP) | VAF 107/577 reads (19%) | called by muse, mutect2, varscan2
- SNRNP200 | c.5544C>T p.I1848= | Silent (SNP) | VAF 55/390 reads (14%) | catalogued as COSV55530935; called by muse, mutect2, varscan2
- TAF11L12 | c.96A>G p.L32= | Silent (SNP) | VAF 42/373 reads (11%) | called by muse, mutect2, varscan2
- XIRP2 | c.2475A>G p.Q825= (on ENST00000628543; = p.Q1000= on NM_152381.6) | Silent (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- ZFP92 | c.795G>A p.A265= | Silent (SNP) | VAF 116/795 reads (15%) | catalogued as rs1451943067, COSV100100161; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1257C>A p.T419= | Silent (SNP) | VAF 48/605 reads (8%) | called by muse, mutect2
- ZNF365 | c.159C>T p.Y53= | Silent (SNP) | VAF 46/442 reads (10%) | catalogued as rs369710448, COSV67925096; called by muse, mutect2, varscan2
- ZNF804A | c.952T>C p.L318= | Silent (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- ABCA8 | c.1789-316G>T | Intron (SNP) | VAF 107/230 reads (47%) | called by muse, mutect2, varscan2
- EXT1 | c.-236C>T | 5'UTR (SNP) | VAF 165/575 reads (29%) | called by muse, mutect2, varscan2
- SLC22A17 | n.187C>T | RNA (SNP) | VAF 99/655 reads (15%) | called by muse, mutect2, varscan2
